Somatic mutation profile of tumor specimen MP2PRT-PASGWZ-TMP1-A (aliquot MP2PRT-PASGWZ-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASGWZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,690 days).
Specimen MP2PRT-PASGWZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1d27791-1227-4d3f-b3fe-b0f7665b8382.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASGWZ-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASGWZ-NB1-B-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d91de23-8954-41c7-bcc4-a6ec0c0aa9bd

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.3836+1G>A p.X1279_splice | Splice Site (SNP) | VAF 125/164 reads (76%) | catalogued as rs200782888, CS056749, COSV52117332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs121918461, CM013415, CM098208, COSV61004983, COSV61005256, COSV61011211; ClinVar: pathogenic; called by muse, mutect2
- AGBL1 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 112/295 reads (38%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.457); catalogued as rs751237894; called by muse, mutect2, varscan2
- CARMIL1 | c.4081G>A p.G1361R | Missense Mutation (SNP) | VAF 66/408 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as rs373424069; called by muse, mutect2, varscan2
- FAM189A2 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 171/416 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs569881416, COSV99975444; called by muse, mutect2, varscan2
- FRMD6 | c.1556G>A p.R519H (on ENST00000344768 / NM_001267046.2; = p.R511H on NM_152330.4) | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs367984773; called by muse, mutect2, varscan2
- INO80D | c.2284G>T p.V762F | Missense Mutation (SNP) | VAF 106/332 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV101305839; called by muse, mutect2, varscan2
- KCNG1 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 188/503 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV65367934, COSV65370367; called by muse, mutect2, varscan2
- KDR | c.2585G>T p.C862F | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755228080; called by muse, mutect2
- LZTR1 | c.2161G>T p.E721* | Nonsense Mutation (SNP) | VAF 179/428 reads (42%) | catalogued as COSV53146508, COSV99302403; called by muse, mutect2, varscan2
- PRSS56 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 188/450 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1422344251; called by muse, mutect2, varscan2
- SPATA31A1 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 108/333 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1296925874; called by muse, mutect2, varscan2
- IFT140 | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- PAK4 | c.581C>A p.A194D | Missense Mutation (SNP) | VAF 224/587 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POU6F2 | c.1953_1956del p.R652Ffs*10 | Frame Shift Del (DEL) | VAF 42/197 reads (21%) | called by pindel*, varscan2
- TENM3 | c.1404C>T p.A468= | Silent (SNP) | VAF 188/613 reads (31%) | catalogued as rs757209056; called by muse, mutect2, varscan2
- TYR | c.936C>A p.L312= | Silent (SNP) | VAF 273/325 reads (84%) | called by muse, mutect2, varscan2
